Surgical pathology report (de-identified scan), TCGA case TCGA-44-3919, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-3919-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Right upper lobe of the lung
- B. Level 10 lymph node
- C. Right lymph node
- D. Right lobe of lung
- E. Level 7

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung lesion.

FROZEN SECTION DIAGNOSIS

AFS: Lung, right upper lobe, wedge biopsy - Adenocarcinoma.

GROSS DESCRIPTION

- A. Received is a container labeled with the patient's name, medical record number and "wedge resection right upper lobe of the lung". The specimen consists of a wedge-shaped fragment of tissue, measuring 6.5 x 4 x 3.5 cm. Green ink is applied to the pleural surface. The specimen is sectioned and is found to contain a 2.5 cm spongy tan nodule which extends to the stapled margin of resection. A portion of the specimen is submitted for tissue procurement. Additionally, frozen section is performed. All tissue minus the staple line is submitted in blocks AFS, A1, A2.
- B. Received fresh, subsequently fixed in formalin, labeled "level 10 lymph node" are multiple black-red irregular rubbery tissue fragments which have an aggregate measurement of 2 x 1 x 0.7 cm. Specimens are entirely submitted in one cassette. AS-1.
- C. Received fresh, subsequently fixed in formalin, labeled "R4 lymph node" is a 3.2 x 2.2 x 1.5 cm pink-red irregular soft friable tissue fragment. The specimen is friable. Also received in the same container is a 1.2 cm pink-black irregular

[page 2 of 3]
GROSS DESCRIPTION

soft tissue fragment. The specimen is entirely submitted as follows. Blocks 1-3 - largest tissue fragment sectioned; block 4 - smaller tissue fragment. AS-4.

D. Received fresh, subsequently fixed and inflated with formalin, labeled "right lobe of lung." The specimen consists of a 14 x 10.5 x 5 cm lobe of lung. The specimen shows multiple staple lines throughout. Possible black softened hilar lymph nodes are grossly identified. The specimen shows a violaceous smooth glistening pleura. There are multiple staple lines present located near the hilum and antihilar. Staple antihilar is removed to show a 3.5 x 2 cm scabrous irregular focus. This focus is inked blue and comes within 4 cm from the hilum. Cut surface of this area

shows possible tumor present measuring 1.2 x 0.6 x 0.3 cm. This grossly involves the staple line. No other discrete gross lesions are identified throughout the remainder of the specimen which shows a red spongy cut surface. Representative sections of the specimen are submitted as follows: Block 1 - bronchial and vascular margins;

block 2 - possible hilar lymphoid tissue; block 3 - representative section of possible tumor at staple line (RS-5).

E. Received fresh, subsequently fixed in formalin, labeled

"E. Level 7" is a 1.7 x 1.2 x 0.6 cm black-pink irregular soft friable tissue fragment. The specimen is bisected and entirely submitted in one cassette. AS-1.

MICROSCOPIC DESCRIPTION

A. The following template applies to the wedge resection of lung:

Histologic type: Adenocarcinoma

Histologic grade: Moderately differentiated

Primary tumor (pT): 2.5 cm. (pT1)

[page 3 of 3]
MICROSCOPIC DESCRIPTION

Margins of resection: Negative on the lobectomy specimen, specimen D.

Venous (large vessel) invasion: Not identified.

Arterial (large vessel) invasion: Not identified.

Lymphatic (small vessel) invasion: Not identified.

Regional lymph nodes (pN): Negative as described below (pN0)

Distant metastasis (pM): Could not be evaluated by the specimen.

Other findings: None.

B. The level 10 lymph nodes demonstrate no evidence of metastasis in six lymph nodes.

C. The R-4 lymph nodes demonstrate no evidence of metastasis in 12 lymph nodes.

D. The right lobe of the lung demonstrates residual adenocarcinoma, 1.5 cm. located at the staple line. Due

to

the orientation of the carcinoma adjacent to the staple line in the wedge resection, this likely represents one edge of the tumor and thus should not be added to the main tumor size. The margins of resection are uninvolved. There is no evidence of metastasis in

six

lymph nodes.

E. There is no metastasis in three level 7 lymph nodes.

3x3, 4x2, 14

DIAGNOSIS

A. Lung, right upper lobe, wedge resection:

Adenocarcinoma, moderately differentiated, 2.5 cm., extending to the staple line.

B. Level 10 lymph nodes, resection:

No evidence of metastasis in six lymph nodes (0/6).

DIAGNOSIS

C. Level R-4 lymph nodes, resection:

No evidence of metastasis in twelve lymph nodes (0/12).

D. Lung, right lobe, lobectomy:

Adenocarcinoma, moderately differentiated, 1.5 cm. at staple line.

No evidence of metastasis in 6 lymph nodes (0/6).

E. Level 7 lymph node, resection:

No evidence of metastasis in three lymph nodes (0/3).

Source: NCI Genomic Data Commons file 93a88ca7-4891-467d-bb2f-a3a130b76957 (TCGA-44-3919.D609482C-704A-4AA9-A0B6-FEB9822CBE96.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).